Somatic mutation profile of tumor specimen 0DWD2A from CCDI case PBCNDV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.9 years (1,429 days).
Specimen 0DWD2A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96e1c3c9-5330-480b-9216-286900ef6e41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWD1L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a4c11d1-7e66-4ee7-ba86-ba894094e360

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSPA12B | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 25/338 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as rs1420311399; called by muse, mutect2
- SIGLEC8 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 104/439 reads (24%) | catalogued as rs370177010; called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 29/804 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- TMEM30B | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2
- ZNF236 | c.3035C>A p.S1012Y | Missense Mutation (SNP) | VAF 110/676 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GMPPB | c.51G>T p.L17= | Silent (SNP) | VAF 42/294 reads (14%) | called by muse, mutect2, varscan2
- ZNF804A | c.2475T>G p.T825= | Silent (SNP) | VAF 44/712 reads (6%) | called by muse, mutect2
- GCLC | c.1402-29A>G | Intron (SNP) | VAF 30/394 reads (8%) | called by muse, mutect2
- WDPCP | c.2159-61A>T | Intron (SNP) | VAF 133/223 reads (60%) | called by muse, mutect2, varscan2
